Somatic mutation profile of tumor specimen TCGA-DJ-A3V4-01A (aliquot TCGA-DJ-A3V4-01A-11D-A22Z-08) from TCGA case TCGA-DJ-A3V4, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 60.8 years (22,218 days).
Specimen TCGA-DJ-A3V4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20613310-daeb-4ffc-812d-3226268b28bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3V4-10A (Blood Derived Normal), aliquot TCGA-DJ-A3V4-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bac2bac-db49-438b-8920-d50fe0282bf7

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Splice Site 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRF4 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99348144; called by muse, varscan2
- ATG2B | c.2677C>G p.L893V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV100738051; called by muse, mutect2, varscan2
- MUC16 | c.30377C>T p.P10126L | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs1241037391, COSV101200034; called by muse, mutect2
- MYO7B | c.3700G>T p.D1234Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101268203, COSV67352634; called by muse, mutect2, varscan2
- SIGLEC8 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs200891335, COSV100367463; called by muse, varscan2
- STATH | c.102+1G>A p.X34_splice | Splice Site (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99887238; called by muse, mutect2, varscan2
- XRCC3 | c.542T>A p.I181N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100572782; called by muse, mutect2, varscan2
- SEC16A | c.407del p.P136Lfs*3 | Frame Shift Del (DEL) | VAF 18/184 reads (10%) | called by mutect2, varscan2
- TNRC6B | c.4968C>G p.T1656= (on ENST00000454349 / NM_001162501.2; = p.T1546= on NM_015088.3) | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100109788, COSV100109942; called by muse, mutect2, varscan2
